Somatic mutation profile of tumor specimen TCGA-17-Z041-01A (aliquot TCGA-17-Z041-01A-01W-0746-08) from TCGA case TCGA-17-Z041, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z041-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4577ff32-ce0d-4147-9fa6-dae4d63cd795.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z041-11A (Solid Tissue Normal), aliquot TCGA-17-Z041-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b8652e8-1c57-405a-8039-ac07bcefb7bb

The open-access MAF lists 51 somatic variants for this specimen: 38 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 12, Nonsense Mutation 3, In Frame Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.6601G>T p.A2201S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs1189104172; called by muse, mutect2
- AOX1 | c.3062G>A p.R1021H | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.108); catalogued as rs896880623, COSV65982520; called by muse, mutect2, varscan2
- DOP1B | c.1094G>C p.R365P | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67693080; called by mutect2, varscan2
- DVL3 | c.1385G>C p.R462T | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100493656; called by muse, mutect2, varscan2
- ESCO1 | c.1057C>G p.Q353E | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV52520696; called by muse, mutect2, varscan2
- FOLH1 | c.1927G>T p.A643S | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.289); catalogued as COSV57049998; called by muse, mutect2, varscan2
- HTR1B | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs544367019; called by muse, mutect2, varscan2
- IRX1 | c.595G>C p.D199H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1161474433; called by mutect2, varscan2
- LARP7 | c.1738G>T p.E580* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as COSV60520896; called by muse, mutect2, varscan2
- LTK | c.2231C>A p.P744H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99540764; called by muse, varscan2
- MYO9B | c.4939G>A p.E1647K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV68277049; called by muse, mutect2
- RET | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV60694867; called by muse, mutect2, varscan2
- SZT2 | c.758C>A p.S253* | Nonsense Mutation (SNP) | VAF 22/113 reads (19%) | catalogued as COSV101285374; called by muse, mutect2, varscan2
- TTN | c.60655C>T p.P20219S (on ENST00000591111; = p.P12795S on NM_003319.4) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | PolyPhen probably damaging (0.998); catalogued as COSV100621963; called by muse, mutect2, varscan2
- ZFHX4 | c.8689G>A p.D2897N | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1227968613, COSV51500031; called by muse, mutect2, varscan2
- ARRB1 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CAAP1 | c.526A>T p.K176* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- FAT4 | c.3476A>G p.H1159R | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FKBP10 | c.994G>C p.G332R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSD2 | c.1735A>G p.I579V | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GBA3 | c.871G>C p.E291Q | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- HEY2 | c.193A>C p.N65H | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IKZF5 | c.152_160del p.Q51_G53del | In Frame Del (DEL) | VAF 30/133 reads (23%) | called by mutect2, varscan2
- LRP1B | c.1144A>C p.K382Q | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.207); called by muse, mutect2
- MC2R | c.696G>T p.W232C | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- N4BP3 | c.1288C>A p.Q430K | Missense Mutation (SNP) | VAF 15/15 reads (100%) | SIFT tolerated (0.71); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- NABP1 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- NAIF1 | c.268G>T p.V90L | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT tolerated (0.36); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NLN | c.903_914del p.D301_L304del | In Frame Del (DEL) | VAF 3/22 reads (14%) | called by pindel, varscan2*
- PCNT | c.8175G>T p.E2725D | Missense Mutation (SNP) | VAF 37/43 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PIK3CB | c.2603G>A p.S868N | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.574); called by mutect2, varscan2
- PIP4K2A | c.159C>G p.S53R | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PLXNA4 | c.2110C>A p.L704M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- SLC27A6 | c.1731G>T p.L577F | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TLN1 | c.3726G>C p.L1242F | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAV18 | c.236G>C p.G79A | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TUBGCP6 | c.2735C>G p.T912S | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT tolerated (0.73); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TUSC3 | c.1022C>A p.P341H | Missense Mutation (SNP) | VAF 57/97 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM22 | c.2022C>T p.F674= | Silent (SNP) | VAF 30/114 reads (26%) | called by muse, mutect2, varscan2
- BICD1 | c.954C>T p.F318= | Silent (SNP) | VAF 13/94 reads (14%) | called by muse, mutect2, varscan2
- COL16A1 | c.861C>T p.S287= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as rs367544171; called by muse, mutect2, varscan2
- DOCK1 | c.2166C>T p.Y722= | Silent (SNP) | VAF 16/344 reads (5%) | called by muse, mutect2
- H2BC18 | c.186C>A p.I62= | Silent (SNP) | VAF 58/814 reads (7%) | catalogued as COSV58943772, COSV58944899; called by muse, mutect2
- HTRA1 | c.1224G>C p.V408= | Silent (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- PLEC | c.12432C>T p.A4144= (on ENST00000322810 / NM_201380.4; = p.A4034= on NM_000445.5) | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs555118583; called by muse, mutect2, varscan2
- RBP3 | c.1674G>C p.S558= | Silent (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- RWDD2A | c.654C>T p.H218= | Silent (SNP) | VAF 41/264 reads (16%) | called by muse, mutect2, varscan2
- SLC35G5 | c.975C>G p.A325= | Silent (SNP) | VAF 42/100 reads (42%) | called by muse, varscan2
- ZNF430 | c.1284C>G p.P428= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as COSV55113178; called by muse, mutect2, varscan2
- ZP2 | c.525T>C p.S175= | Silent (SNP) | VAF 27/70 reads (39%) | called by muse, mutect2, varscan2
- ETNK2 | c.1015-103C>G | Intron (SNP) | VAF 34/316 reads (11%) | called by muse, mutect2
